Somatic mutation profile of tumor specimen TARGET-50-PAJPAR-01A (aliquot TARGET-50-PAJPAR-01A-01D) from TARGET case TARGET-50-PAJPAR, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: female; Vital status: Dead; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 5.3 years (1,950 days).
Specimen TARGET-50-PAJPAR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b438696-4645-42b0-82d5-38d596dd5977.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAJPAR-11A (Solid Tissue Normal), aliquot TARGET-50-PAJPAR-11A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e6a3c80-020b-4ef9-a054-a539fdcc3289

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Nonsense Mutation 1, In Frame Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 26/32 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: pathogenic / likely pathogenic / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- CAPN15 | c.2272C>T p.H758Y | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV54839415; called by muse, mutect2
- SNX24 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 16/32 reads (50%) | catalogued as rs781702985, COSV54446920; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.2060G>A p.C687Y | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV61458899; called by muse, mutect2, varscan2
- EMC4 | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- FAM184B | c.1914G>C p.R638S | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- PCDHGB5 | c.1565_1567dup p.R522_T523insS | In Frame Ins (INS) | VAF 25/56 reads (45%) | called by mutect2, pindel, varscan2
- SLC2A12 | c.1843C>T p.P615S | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHB7 | c.1041G>T p.L347= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV50786770; called by muse, mutect2
- SNX4 | c.198A>G p.E66= | Silent (SNP) | VAF 7/103 reads (7%) | called by muse, mutect2
- WBP1L | c.879T>C p.G293= | Silent (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- COL6A2 | c.2461+2385T>C | Intron (SNP) | VAF 14/17 reads (82%) | called by muse, mutect2, varscan2
